Somatic mutation profile of tumor specimen TCGA-55-7573-01A (aliquot TCGA-55-7573-01A-11D-2036-08) from TCGA case TCGA-55-7573, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,302 days).
Specimen TCGA-55-7573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 373968cd-7c79-4afb-90ab-454820370a50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7573-11A (Solid Tissue Normal), aliquot TCGA-55-7573-11A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d565875-6f49-4f18-9f4b-eb35996e0478

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, RNA 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, varscan2
- AFF2 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54001037; called by muse, mutect2, varscan2
- ARX | c.1013A>T p.Y338F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as CX085852; called by muse, mutect2
- ASB12 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV62857449; called by muse, mutect2, varscan2
- CCDC57 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV58936578; called by muse, mutect2, varscan2
- CDC42BPG | c.3926G>T p.R1309L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771014382, COSV61347715, COSV61348584; called by muse, mutect2, varscan2
- CDHR2 | c.3789C>G p.I1263M | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56143058; called by muse, mutect2, varscan2
- CUL1 | c.2266C>G p.L756V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57391249; called by muse, mutect2, varscan2
- DLG3 | c.2046G>A p.M682I (on ENST00000374360 / NM_021120.4; = p.M377I on NM_020730.3) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52085742, COSV99529376; called by muse, mutect2, varscan2
- DNAJB6 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV51098491; called by muse, mutect2, varscan2
- EIF4G2 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV60598498; called by muse, mutect2
- ELF3 | c.909del p.F303Lfs*22 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as COSV62837952; called by mutect2, pindel, varscan2
- ENTR1 | c.548G>T p.G183V (on ENST00000357365 / NM_001039707.2; = p.G160V on NM_006643.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV53742684; called by muse, mutect2, varscan2
- ERCC6 | c.4186A>G p.R1396G | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745352643, COSV63393191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXTL1 | c.1118T>G p.I373S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65338123; called by muse, mutect2, varscan2
- FBXO21 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.257); catalogued as COSV57972420; called by muse, mutect2
- GP2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV56895797; called by muse, mutect2, varscan2
- GTF3C4 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64645653; called by muse, mutect2, varscan2
- HGF | c.1321del p.R441Efs*37 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV55945541; called by mutect2, varscan2
- HMCN1 | c.9304G>T p.E3102* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV54926839; called by muse, mutect2, varscan2
- ITGA1 | c.3119G>A p.S1040N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV50891947; called by muse, mutect2, varscan2
- L3MBTL3 | c.1789C>A p.P597T | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV62387968; called by muse, mutect2, varscan2
- LAMC3 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1418447793, COSV63094199; called by muse, mutect2
- LETM2 | c.450G>T p.M150I (on ENST00000379957 / NM_001286819.2; = p.M103I on NM_144652.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV52687443; called by muse, mutect2, varscan2
- NCOR1 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV51963652, COSV51980479, COSV51988436; called by muse, mutect2, varscan2
- NUP85 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV55463136, COSV55465863; called by muse, mutect2, varscan2
- OR4S2 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as rs751192960, COSV56745977, COSV56747868; called by muse, mutect2, varscan2
- OTUB1 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1436275463, COSV55365230; called by muse, mutect2, varscan2
- PKD1L1 | c.5321T>C p.V1774A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV56973678; called by muse, mutect2, varscan2
- PTCHD3 | c.1471A>T p.T491S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV71257179; called by muse, mutect2, varscan2
- SCFD2 | c.1707+2C>T p.X569_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV66374638; called by muse, mutect2, varscan2
- SLC36A4 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs373834484, COSV58397218; called by muse, mutect2, varscan2
- SNX8 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56129115; called by muse, varscan2
- TECRL | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV101168296, COSV67089450; called by muse, mutect2, varscan2
- TROAP | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV57745377; called by muse, mutect2, varscan2
- ZDBF2 | c.1057T>C p.F353L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100985622, COSV65628745; called by muse, mutect2, varscan2
- ZFHX4 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50704586; called by muse, mutect2, varscan2
- ZNF148 | c.2199C>G p.F733L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV62305316, COSV62306707; called by muse, mutect2, varscan2
- DUXA | c.484del p.R162Gfs*7 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel, varscan2
- LUC7L3 | c.306_317del p.G103_R106del | In Frame Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel
- OR2J2 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by muse, mutect2
- TADA2B | c.678dup p.N227Qfs*46 | Frame Shift Ins (INS) | VAF 27/134 reads (20%) | called by mutect2, pindel, varscan2
- BRWD3 | c.373C>T p.L125= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100956353; called by mutect2, varscan2
- CEP72 | c.1254G>T p.L418= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV53795674; called by muse, mutect2, varscan2
- GPA33 | c.117C>T p.V39= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1482300202, COSV63301382, COSV63301873; called by muse, mutect2, varscan2
- IFT172 | c.2781G>A p.E927= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99563014; called by muse, mutect2, varscan2
- KIDINS220 | c.2313C>T p.V771= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV56757393; called by muse, mutect2, varscan2
- MRM2 | c.33C>T p.S11= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV54248860; called by muse, mutect2, varscan2
- OR2M5 | c.273C>G p.S91= | Silent (SNP) | VAF 153/491 reads (31%) | catalogued as rs755121594, COSV63546783, COSV63547305; called by muse, mutect2, varscan2
- PLD6 | c.588G>T p.R196= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV58634345; called by muse, mutect2, varscan2
- TTI1 | c.1110C>T p.L370= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as rs762948089, COSV65061121; called by muse, mutect2, varscan2
- ZFHX4 | c.1224G>C p.L408= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs13250763, COSV99265992; called by muse, mutect2, varscan2
- FAM21FP | n.1107C>T | RNA (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- PRR12 | c.51+432G>T | Intron (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55871020; called by muse, mutect2, varscan2
- SLIT3 | c.1459+4623G>T | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as COSV60626030; called by muse, mutect2, varscan2
- SNORD115-3 | n.17C>A | RNA (SNP) | VAF 29/387 reads (7%) | called by muse, mutect2
